CCDI case PBCCVL — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Bones, joints and articular cartilage of other and unspecified sites.
https://portal.gdc.cancer.gov/cases/d4b692b6-1c7f-4fc9-ae58-a9878fe30637

Demographics
Sex at birth: male.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Bones of skull and face and associated joints; Age at diagnosis: 4.7 years (1,720 days).

Biospecimens (3 samples)
- Sample 0DPZT9: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DPZTS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DPZUA: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
